CCDI case PBBVLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Rectosigmoid junction.
https://portal.gdc.cancer.gov/cases/93113807-8409-4011-a6b7-7b31c0d53b9b

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Metastatic signet ring cell carcinoma: ICD-O-3 morphology code: 8490/6; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 12.4 years (4,530 days).

Biospecimens (3 samples)
- Sample 0DI7SF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI7V1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DI7VJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
